MMRF case MMRF_2269 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/14469c41-becd-4e3b-8511-dd1ffca66087

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.9 years (25,162 days); ISS stage: II; Days to last known disease status: 809 days (2.2 years); Days to last follow up: 809 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 117 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 134 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -19 (ECOG 0): M Protein 5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 1.12 g/L; Immunoglobulin A 82 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 4.8 µg/mL; Lactate Dehydrogenase 1.53 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.9 mmol/L; Albumin 28 g/L; Total Protein 11.4 g/dL; Glucose 7.32 mmol/L.
- Day 43 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.22 mg/dL; Hemoglobin 7.75 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 326 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 6.22 mmol/L.
- Day 134 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 5.34 mmol/L.
- Day 253 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.53 mg/dL; Immunoglobulin G 6.65 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 284 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.68 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.56 mmol/L.
- Day 337 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.12 mmol/L.
- Day 383 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 9.99 g/L; Immunoglobulin A 1.98 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.88 ×10⁹/L; Absolute Neutrophil 3.26 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.5 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 4.95 mmol/L.
- Day 542 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 9.93 g/L; Immunoglobulin A 2 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.55 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 4.29 mmol/L.
- Day 633 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 9.72 g/L; Immunoglobulin A 2.15 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 4.82 ×10⁹/L; Absolute Neutrophil 2.59 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.6 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 4.79 mmol/L.
- Day 725 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.88 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 2.45 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.89 ×10⁹/L; Absolute Neutrophil 3.32 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.5 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 3.8 mmol/L.
- Day 809 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 9.83 g/L; Immunoglobulin A 2.39 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.17 mmol/L.

Other clinical attributes
- Day -19: Weight: 115 kg; Height: 165 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2269_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -19 days.
- Sample MMRF_2269_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -19 days.
